CPTAC case C3L-01885 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ae395b9-0a62-40dc-b476-ad60aa70991a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 67.8 years (24,752 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 342 days; Progression or recurrence: no; Days to last follow up: 342 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 2.7 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (2 entries)
- Days to follow up: 342 days; Disease response: Tumor Free.
- Days to follow up: 342 days; Disease response: Complete Response.

Other clinical attributes
- Weight: 108 kg; Height: 175 cm; BMI: 35.27.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 37.5; Cigarettes per day: 50; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 1975; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 15.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01885-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 231 mg.
- Sample C3L-01885-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 227 mg.
- Sample C3L-01885-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 212 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01885-23: Section location: Right; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-01885-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 396 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01885-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
